Gene-level copy-number profile of tumor specimen TCGA-AX-A2H2-01A from TCGA case TCGA-AX-A2H2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 86.3 years (31,524 days).
Specimen TCGA-AX-A2H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.9a6c0f2b-6ca5-44a6-a001-e8885156ef94.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A2H2-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62c5ae41-79f3-4240-98a4-e8cd490cdaaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 792; copy number 2: 20,175; copy number 3: 21,170; copy number 4: 10,310; copy number 5: 3,992; copy number 6: 2,443; copy number 7: 402; copy number 8: 122; copy number 9: 131; copy number 10: 96; copy number 11: 60; copy number 12: 13; copy number 14: 2; copy number 16: 10; copy number 18: 16; copy number 27: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A2H2-01A-11D-A17U-01): tumor purity 0.63, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:193,304,745–193,365,953, 1 gene: LINC01031.
- chr4:180,731,164–181,265,145, 4 genes: AC104803.1, LINC00290, AC019235.1, LINC02500.
- chr5:60,021,249–60,304,151, 2 genes: AC034234.1, RNU6-806P.
- chr6:97,710,953–97,717,197, 1 gene: AL080316.1.
- chr10:54,486,230–54,656,051, 3 genes: AL353784.1, NEFMP1, MIR548F1.
- chr14:68,113,706–68,422,196, 6 genes: AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,067 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,357,854–153,671,028, 26 genes, copy number 5: S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5, S100A4, S100A3, S100A2, BX470102.2, S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2.
- chr2:38,814–45,612,165, 760 genes, copy number 5–6 (broad region; genes not listed).
- chr2:47,045,538–67,412,089, 313 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:68,023,694–79,185,523, 248 genes, copy number 5 (broad region; genes not listed).
- chr2:87,194,786–95,547,545, 216 genes, copy number 5 (broad region; genes not listed).
- chr2:110,386,411–110,716,595, 11 genes, copy number 6 (within-gene range 1–6): AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1.
- chr2:111,295,629–114,420,302, 97 genes, copy number 8–16 (broad region; genes not listed).
- chr3:11,745–2,089,211, 21 genes, copy number 5: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144.
- chr3:88,317,156–91,513,775, 16 genes, copy number 6: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr3:142,580,910–174,378,005, 465 genes, copy number 6 (broad region; genes not listed).
- chr3:175,473,919–198,222,513, 492 genes, copy number 6–8 (broad region; genes not listed).
- chr4:51,843,000–82,384,027, 483 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–4,440,259, 96 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:132,086,266–139,036,042, 100 genes, copy number 6–18 (broad region; genes not listed).
- chr8:36,378,069–37,331,991, 10 genes, copy number 6 (within-gene range 4–6): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1.
- chr8:38,844,866–43,674,591, 113 genes, copy number 5–8 (broad region; genes not listed).
- chr8:79,762,371–81,284,777, 45 genes, copy number 5 (within-gene range 3–5): HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr8:90,058,608–91,398,155, 20 genes, copy number 5 (within-gene range 4–5): CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:94,127,162–98,093,610, 76 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:110,899,996–125,541,373, 168 genes, copy number 5–7 (broad region; genes not listed).
- chr8:126,325,454–131,317,632, 66 genes, copy number 5–9 (broad region; genes not listed).
- chr8:132,507,962–133,409,107, 17 genes, copy number 5: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6.
- chr10:12,877,459–14,462,142, 37 genes, copy number 6 (within-gene range 4–6): AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265.
- chr10:77,350,851–77,966,440, 14 genes, copy number 5 (within-gene range 4–5): KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP.
- chr10:88,259,129–93,806,272, 118 genes, copy number 6 (broad region; genes not listed).
- chr11:41,122,907–43,880,726, 36 genes, copy number 6–7 (within-gene range 4–7): RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4.
- chr11:62,213,427–62,921,807, 66 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:64,987,945–65,326,543, 34 genes, copy number 6: BATF2, ARL2, ARL2-SNX15, MIR6879, AP000436.1, SNX15, SAC3D1, NAALADL1, CDCA5, ZFPL1, TMEM262, VPS51, AP003068.1, TM7SF2, ZNHIT2, AP003068.3, AP003068.4, FAU, SYVN1, MRPL49, MIR6751, HIGD1AP10, RNU2-23P, PDCL2P2, SPDYC, PGAM1P8, AP003068.2, CAPN1, SLC22A20P, AP000944.6, POLA2, AP000944.5, AP000944.7, CDC42EP2.
- chr11:102,047,437–103,479,863, 46 genes, copy number 6 (within-gene range 4–6): CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr12:47,593,208–47,837,898, 15 genes, copy number 6: AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354.
- chr12:50,763,710–56,688,408, 331 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:101,452,593–114,132,623, 185 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:42,968,088–83,095,122, 1,333 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:10,252,268–17,788,568, 441 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:44,382,298–46,231,243, 107 genes, copy number 6–27 (broad region; genes not listed).
- chr20:47,071,865–47,786,616, 15 genes, copy number 5 (within-gene range 4–5): AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1.
- chr20:62,388,632–64,313,132, 120 genes, copy number 5–9 (broad region; genes not listed).
- chr22:29,978,950–30,674,134, 41 genes, copy number 5: AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2.
- chr22:30,731,557–31,618,588, 41 genes, copy number 5 (within-gene range 3–5): MIR3200, EIF4HP2, MORC2-AS1, MORC2, TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1, AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3, AC005005.1, MIR3928, RNF185, RNF185-AS1, LIMK2, RNU6-1128P, Y_RNA, PIK3IP1, PIK3IP1-DT, RNA5SP496, PATZ1, LINC01521, RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1.
- chr22:36,754,086–40,636,719, 162 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
